Somatic mutation profile of tumor specimen ALCH-B3C3-TTP1-A (aliquot ALCH-B3C3-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3C3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.1 years (26,717 days).
Specimen ALCH-B3C3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 686d9d67-2e18-4aff-87b2-9d19f26e5077.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3C3-NB1-A (Blood Derived Normal), aliquot ALCH-B3C3-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28616de5-890a-4ec8-b02d-aeb017c91e7e

The open-access MAF lists 53 somatic variants for this specimen: 31 protein-altering or splice-affecting, 13 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 13, Intron 4, Splice Region 3, 3'UTR 2, 5'UTR 2, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP46 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as rs545569303; called by muse, mutect2, varscan2
- COMP | c.80-4G>A | Splice Region (SNP) | VAF 32/135 reads (24%) | catalogued as rs765529970; called by muse, mutect2, varscan2
- JPH2 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as rs760723899; called by muse, mutect2
- KIF3A | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 38/403 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs756676830; called by muse, mutect2
- KNL1 | c.1613C>T p.P538L (on ENST00000346991 / NM_170589.5; = p.P512L on NM_144508.5) | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as rs1207628660; called by muse, mutect2
- MAGI1 | c.2239C>T p.H747Y | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.43); catalogued as rs763358402; called by muse, mutect2, varscan2
- NR1H4 | c.903G>C p.L301F (on ENST00000551379 / NM_001206993.2; = p.L287F on NM_005123.4) | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as rs1244307438; called by muse, mutect2, varscan2
- NTRK1 | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 68/374 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs1292790967, COSV62324793; called by muse, mutect2, varscan2
- PASK | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs766475442, COSV99299070; called by muse, mutect2, varscan2
- PCDHA4 | c.1429G>A p.V477M | Missense Mutation (SNP) | VAF 41/460 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs549483688; called by muse, mutect2
- PTDSS1 | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 20/349 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as rs202206461; called by muse, mutect2
- RAI1 | c.4817C>T p.A1606V | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.207); catalogued as rs771535517, COSV99884059; called by muse, mutect2, varscan2
- SPTBN4 | c.5266G>A p.G1756S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374849113; called by mutect2, varscan2
- TCF21 | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs774624032; called by muse, mutect2
- TTN | c.31003C>T p.P10335S (on ENST00000591111; = p.P9408S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/182 reads (13%) | PolyPhen probably damaging (0.998); catalogued as COSV60024222; called by muse, mutect2, varscan2
- UNC13D | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 42/351 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1289693454; called by muse, mutect2, varscan2
- ATAD2 | c.3631G>A p.D1211N | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CAPN12 | c.730-8C>T | Splice Region (SNP) | VAF 34/158 reads (22%) | called by muse, mutect2, varscan2
- CRIP2 | c.96C>G p.C32W | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EGFR | c.2311_2312insGCACGGACA p.D770_N771insSTD | In Frame Ins (INS) | VAF 24/165 reads (15%) | called by mutect2, pindel, varscan2
- FRS2 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 36/333 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- HUWE1 | c.6961G>C p.G2321R | Missense Mutation (SNP) | VAF 97/495 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCP | c.576C>T p.C192= | Splice Region (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- KRT16 | c.799G>C p.G267R | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MIA3 | c.3825T>A p.N1275K | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2
- SPAG4 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (1); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SRGAP3 | c.40A>G p.I14V | Missense Mutation (SNP) | VAF 57/463 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SYNE2 | c.13238A>G p.Y4413C | Missense Mutation (SNP) | VAF 32/480 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- TMEM131 | c.5396G>T p.W1799L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- VRK1 | c.982C>G p.L328V | Missense Mutation (SNP) | VAF 17/251 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.821); called by muse, mutect2
- ZNF600 | c.581T>C p.V194A | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.471); called by muse, mutect2
- CACNB1 | c.1092C>T p.S364= | Silent (SNP) | VAF 26/277 reads (9%) | catalogued as COSV59999111; called by muse, mutect2
- CPED1 | c.2133A>G p.L711= | Silent (SNP) | VAF 19/150 reads (13%) | catalogued as rs1386533229; called by muse, mutect2, varscan2
- CXorf38 | c.105C>T p.F35= | Silent (SNP) | VAF 16/190 reads (8%) | catalogued as rs980714067; called by muse, mutect2
- DMD | c.8766C>T p.S2922= | Silent (SNP) | VAF 52/650 reads (8%) | catalogued as rs149776669, COSV58897982; ClinVar: likely benign; called by muse, mutect2
- KCNK13 | c.357G>A p.A119= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs1187293454; called by muse, mutect2, varscan2
- LAMA3 | c.9756C>T p.I3252= (on ENST00000313654 / NM_198129.4; = p.I1643= on NM_000227.6) | Silent (SNP) | VAF 89/467 reads (19%) | catalogued as COSV52543385; called by muse, mutect2, varscan2
- OR10Q1 | c.519C>T p.C173= | Silent (SNP) | VAF 39/379 reads (10%) | catalogued as COSV57469769; called by muse, mutect2, varscan2
- PDZRN3 | c.528C>T p.R176= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV55195904; called by muse, mutect2, varscan2
- SLC25A47 | c.258C>T p.Y86= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as rs147080547; called by muse, mutect2
- SYT14 | c.741G>A p.S247= | Silent (SNP) | VAF 25/358 reads (7%) | catalogued as rs370207388; called by muse, mutect2
- TOM1L1 | c.600A>G p.E200= | Silent (SNP) | VAF 21/222 reads (9%) | called by muse, mutect2
- TSSK4 | c.534T>C p.P178= | Silent (SNP) | VAF 13/144 reads (9%) | called by muse, mutect2
- XPR1 | c.1023C>T p.V341= | Silent (SNP) | VAF 20/212 reads (9%) | called by muse, mutect2
- CCDC40 | c.*39G>C | 3'UTR (SNP) | VAF 13/109 reads (12%) | called by muse, mutect2, varscan2
- DGKI | c.*29G>A | 3'UTR (SNP) | VAF 34/271 reads (13%) | catalogued as rs1426548021; called by muse, mutect2, varscan2
- EFHC1 | c.723+266C>A | Intron (SNP) | VAF 60/407 reads (15%) | called by muse, mutect2, varscan2
- LTN1 | c.-33C>T | 5'UTR (SNP) | VAF 30/352 reads (9%) | catalogued as rs1401899992, COSV57478655; called by muse, mutect2
- MT1X | c.-23C>T | 5'UTR (SNP) | VAF 18/196 reads (9%) | called by muse, mutect2
- OFCC1 | n.1450A>T | RNA (SNP) | VAF 80/332 reads (24%) | called by muse, mutect2, varscan2
- RASGRF2 | c.1390+257C>T | Intron (SNP) | VAF 22/166 reads (13%) | catalogued as rs1415243221; called by muse, mutect2, varscan2
- RCC1L | c.584-21G>T | Intron (SNP) | VAF 42/498 reads (8%) | called by muse, mutect2
- TMTC1 | c.939-27538C>T | Intron (SNP) | VAF 30/194 reads (15%) | called by muse, varscan2
